Somatic mutation profile of tumor specimen C3L-06195-03 (aliquot CPT0424530009) from CPTAC case C3L-06195, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 52.0 years (19,009 days).
Specimen C3L-06195-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3306ca20-8dba-4f6e-a7f7-de724babeb5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06195-31 (Blood Derived Normal), aliquot CPT0424660003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90820cc6-aec9-4322-aef6-b70c9d848f9c

The open-access MAF lists 653 somatic variants for this specimen: 404 protein-altering or splice-affecting, 220 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 373, Silent 220, Nonsense Mutation 21, Intron 14, Splice Region 5, 3'UTR 5, 5'Flank 4, Splice Site 3, RNA 3, 3'Flank 2, 5'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDK4 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 164/258 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs104894340, CM980320, COSV56983700, COSV56984378; ClinVar: pathogenic / risk factor / likely pathogenic; called by muse, mutect2, varscan2
- NOTCH2 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 82/363 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs312262794, CM1110713; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PLA2G6 | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 90/382 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs387906863, CM106768, COSV59271908; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ADAM18 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated (0.94); PolyPhen benign (0.015); catalogued as COSV55844140; called by muse, mutect2, varscan2
- ADCY7 | c.1955G>A p.G652E | Missense Mutation (SNP) | VAF 143/297 reads (48%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs767696450; called by muse, mutect2, varscan2
- ADGRF2 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 152/371 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV57286430; called by muse, mutect2, varscan2
- ADGRF3 | c.337G>A p.D113N (on ENST00000311519 / NM_001145168.1; = p.D54N on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 155/374 reads (41%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.012); catalogued as rs775954795; called by muse, mutect2, varscan2
- ADGRF4 | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 80/263 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.185); catalogued as rs1296218344, COSV51952537; called by muse, mutect2, varscan2
- ADGRG7 | c.1726G>A p.G576R | Missense Mutation (SNP) | VAF 77/175 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267599513; called by muse, mutect2, varscan2
- ADPRHL1 | c.5212G>A p.E1738K | Missense Mutation (SNP) | VAF 245/1056 reads (23%) | SIFT tolerated, low confidence (0.12); catalogued as rs1265878146; called by muse, varscan2
- AK9 | c.2770G>A p.E924K | Missense Mutation (SNP) | VAF 93/159 reads (58%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.696); catalogued as rs751308852, COSV58136915; called by muse, mutect2, varscan2
- AMY1C | c.879G>A p.K293= | Splice Region (SNP) | VAF 23/233 reads (10%) | catalogued as COSV64407220; called by muse, mutect2
- AMZ1 | c.476G>A p.G159D | Missense Mutation (SNP) | VAF 119/475 reads (25%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.819); catalogued as rs1178404027; called by muse, mutect2, varscan2
- APOB | c.6649C>T p.H2217Y | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV51947162; called by muse, mutect2, varscan2
- APOBEC3G | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 94/381 reads (25%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.527); catalogued as rs778787955, COSV68470786; called by muse, mutect2, varscan2
- ARMC4 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV99518282; called by muse, mutect2, varscan2
- ARSF | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 190/321 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV63839996, COSV63841355; called by muse, mutect2, varscan2
- ASZ1 | c.75G>A p.W25* | Nonsense Mutation (SNP) | VAF 165/412 reads (40%) | catalogued as COSV99498331; called by muse, mutect2, varscan2
- B4GALT7 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1199510691, COSV50353644; called by muse, mutect2, varscan2
- C20orf85 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 85/412 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs146409192; called by muse, mutect2, varscan2
- C7 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 220/346 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.277); catalogued as COSV57478955; called by muse, mutect2, varscan2
- C7 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV57471178; called by muse, mutect2
- CARD11 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 180/345 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101210606; called by muse, mutect2, varscan2
- CATSPERB | c.1562G>A p.G521E | Missense Mutation (SNP) | VAF 63/249 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.09); catalogued as COSV56422895; called by muse, mutect2, varscan2
- CCDC168 | c.9799C>T p.P3267S | Missense Mutation (SNP) | VAF 109/288 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV59419238; called by muse, mutect2, varscan2
- CCDC170 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 175/284 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs267600858, COSV53337046; called by muse, mutect2, varscan2
- CCDC180 | c.3947G>A p.R1316Q | Missense Mutation (SNP) | VAF 120/230 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139571342; called by muse, mutect2, varscan2
- CCNB3 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 182/274 reads (66%) | SIFT tolerated (0.3); PolyPhen benign (0.063); catalogued as COSV99328770; called by muse, mutect2, varscan2
- CECR2 | c.2125G>A p.E709K (on ENST00000342247 / NM_001290047.2; = p.E526K on NM_001290046.1) | Missense Mutation (SNP) | VAF 168/474 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV52835320; called by muse, mutect2, varscan2
- CFAP53 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 134/372 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs550993731, COSV68351359; called by muse, mutect2, varscan2
- CNGA2 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 211/362 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs755262067; called by muse, mutect2, varscan2
- COL4A5 | c.3493G>A p.E1165K | Missense Mutation (SNP) | VAF 204/329 reads (62%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.867); catalogued as rs771538814, COSV60356642; called by muse, mutect2, varscan2
- COL6A5 | c.4519G>A p.E1507K | Missense Mutation (SNP) | VAF 160/340 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.122); catalogued as COSV99594331; called by muse, mutect2, varscan2
- COL7A1 | c.6025G>T p.G2009* | Nonsense Mutation (SNP) | VAF 145/597 reads (24%) | catalogued as CM970376; called by muse, mutect2, varscan2
- COLQ | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 78/207 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as CM980416; called by muse, mutect2, varscan2
- CSMD2 | c.5278G>A p.E1760K | Missense Mutation (SNP) | VAF 117/432 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs1224226314, COSV53929752; called by muse, mutect2, varscan2
- CSMD2 | c.3103G>A p.D1035N | Missense Mutation (SNP) | VAF 148/325 reads (46%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as rs754391035, COSV53902706, COSV99591642; called by muse, mutect2, varscan2
- CTSG | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 71/299 reads (24%) | catalogued as COSV53535372; called by muse, mutect2, varscan2
- CYP2C8 | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 79/246 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV64877590; called by muse, mutect2, varscan2
- CYP2C9 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 76/287 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV53246644, COSV53246804; called by muse, mutect2, varscan2
- CYYR1 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 64/370 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV100176823; called by muse, mutect2, varscan2
- DCLK1 | c.2213C>T p.S738L (on ENST00000360631 / NM_001330072.2; = p.S431L on NM_001195416.2) | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT tolerated, low confidence (0.37); PolyPhen possibly damaging (0.885); catalogued as COSV55215703; called by muse, mutect2, varscan2
- DIP2B | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 105/176 reads (60%) | catalogued as COSV56582941, COSV99999095; called by muse, mutect2, varscan2
- DISC1 | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 254/520 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs78852015, COSV54417890; called by muse, mutect2, varscan2
- DSG4 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100356360; called by muse, mutect2, varscan2
- DSG4 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 97/297 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs1180274841; called by muse, mutect2, varscan2
- EBF1 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 136/252 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs766532365, COSV58173698, COSV58178759; called by muse, varscan2
- ELAPOR2 | c.3031G>A p.E1011K (on ENST00000450689 / NM_001142749.3; = p.E844K on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as COSV51884232, COSV51888478; called by muse, mutect2, varscan2
- ELFN2 | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 173/400 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.114); catalogued as COSV68743808; called by muse, mutect2, varscan2
- ELL | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 41/225 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV53215280; called by muse, mutect2, varscan2
- ERCC8 | c.113T>C p.V38A | Missense Mutation (SNP) | VAF 59/108 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs1561514955; called by muse, mutect2, varscan2
- ERICH3 | c.3955G>A p.D1319N | Missense Mutation (SNP) | VAF 103/468 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs761450225, COSV58602353; called by muse, mutect2, varscan2
- FAM131B | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 131/379 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs1336634388; called by muse, mutect2, varscan2
- FAT4 | c.11309G>A p.R3770Q | Missense Mutation (SNP) | VAF 159/350 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs540725305, COSV58683662; called by muse, mutect2, varscan2
- FCGR2A | c.368G>A p.W123* (on ENST00000271450 / NM_001136219.3; = p.W122* on NM_021642.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 63/395 reads (16%) | catalogued as COSV54838638, COSV54841069; called by muse, mutect2
- FGD5 | c.1667G>A p.R556Q | Missense Mutation (SNP) | VAF 165/389 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.421); catalogued as rs765601008; called by muse, mutect2, varscan2
- FGFR4 | c.2154G>A p.L718= | Splice Region (SNP) | VAF 32/358 reads (9%) | catalogued as rs200192467; called by muse, mutect2
- FKBP1C | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 153/428 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1292682695; called by muse, mutect2
- FOXA3 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 95/479 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs764817302, COSV56215129; called by muse, mutect2, varscan2
- FOXB2 | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 116/391 reads (30%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as rs868778376; called by muse, mutect2, varscan2
- GABRB3 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 51/233 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs144496462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLI3 | c.3188C>T p.S1063F | Missense Mutation (SNP) | VAF 354/685 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67885604, COSV67888266; called by muse, mutect2, varscan2
- GPR152 | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 228/473 reads (48%) | SIFT tolerated (1); PolyPhen possibly damaging (0.762); catalogued as rs148000171; called by muse, mutect2, varscan2
- GPR65 | c.210G>A p.W70* | Nonsense Mutation (SNP) | VAF 66/279 reads (24%) | catalogued as COSV50862511; called by muse, mutect2
- GPR88 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 90/474 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV59291278; called by muse, mutect2, varscan2
- GPX6 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 190/550 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs761502681; called by muse, varscan2
- GRB7 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 90/366 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs747672743; called by muse, mutect2, varscan2
- H2BE1 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 179/556 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as rs879049714; called by muse, mutect2, varscan2
- HDAC9 | c.909G>A p.M303I | Missense Mutation (SNP) | VAF 53/232 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV67771105; called by muse, mutect2, varscan2
- HDAC9 | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 55/234 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.041); catalogued as COSV67774064; called by muse, mutect2, varscan2
- HESX1 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 107/246 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as rs1211787671; called by muse, mutect2, varscan2
- HNRNPU | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 97/677 reads (14%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.349); catalogued as rs1428436177; called by muse, mutect2, varscan2
- HRNR | c.6577G>A p.G2193R | Missense Mutation (SNP) | VAF 270/2039 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as rs757883430, COSV64254381; called by muse, mutect2, varscan2
- HSD17B12 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99550435; called by muse, mutect2, varscan2
- HSD17B6 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 167/295 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs748272603, COSV59107339; called by muse, mutect2, varscan2
- HSPG2 | c.2783G>A p.G928D | Missense Mutation (SNP) | VAF 77/334 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766952546; called by muse, mutect2, varscan2
- IARS2 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 82/485 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56962095; called by muse, mutect2, varscan2
- ICE2 | c.1702C>T p.L568F | Missense Mutation (SNP) | VAF 86/212 reads (41%) | SIFT tolerated (0.79); PolyPhen benign (0.086); catalogued as rs1249229251, COSV55030379; called by muse, mutect2, varscan2
- ILDR1 | c.1087G>A p.D363N (on ENST00000344209 / NM_001199799.2; = p.D319N on NM_175924.4) | Missense Mutation (SNP) | VAF 132/526 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs751310993, COSV99879035; called by muse, mutect2, varscan2
- ITGA11 | c.3256G>A p.G1086R | Missense Mutation (SNP) | VAF 132/296 reads (45%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.964); catalogued as COSV100241222; called by muse, mutect2, varscan2
- ITPRID1 | c.2845G>A p.E949K | Missense Mutation (SNP) | VAF 224/416 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.534); catalogued as rs921156846; called by muse, mutect2, varscan2
- JAKMIP2 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as COSV54600193; called by muse, mutect2
- KIAA0319 | c.883G>A p.V295I | Missense Mutation (SNP) | VAF 157/511 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1403290447, COSV104427835; called by muse, mutect2, varscan2
- KIAA1210 | c.3674C>T p.P1225L | Missense Mutation (SNP) | VAF 267/422 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as rs772816619; called by muse, mutect2, varscan2
- KLHL10 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 92/215 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV53172723, COSV99505293; called by muse, mutect2, varscan2
- KRTAP5-10 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 52/300 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.394); catalogued as COSV64795824; called by muse, mutect2, varscan2
- LAIR2 | c.83G>A p.R28K | Missense Mutation (SNP) | VAF 213/468 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0.247); catalogued as COSV56622906; called by muse, mutect2, varscan2
- LIPI | c.1012G>A p.G338R | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1486319913; called by muse, mutect2, varscan2
- LMLN | c.1790C>T p.S597L | Missense Mutation (SNP) | VAF 149/327 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); catalogued as rs781558126; called by muse, mutect2, varscan2
- LRIG1 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 121/283 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0.321); catalogued as rs557523202; called by muse, mutect2, varscan2
- LRRC20 | c.544C>T p.P182S (on ENST00000355790 / NM_207119.3; = p.P126S on NM_018205.4) | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1564605149; called by muse, mutect2, varscan2
- LRRC55 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 107/404 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs956237277, COSV101546714; called by muse, mutect2, varscan2
- LRSAM1 | c.1913-1G>A p.X638_splice | Splice Site (SNP) | VAF 160/242 reads (66%) | catalogued as rs756880678, CS105451; ClinVar: conflicting interpretations of pathogenicity / pathogenic; called by muse, mutect2, varscan2
- LUZP1 | c.2305A>G p.M769V | Missense Mutation (SNP) | VAF 53/257 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as rs1420539473; called by muse, mutect2, varscan2
- LZIC | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 70/143 reads (49%) | catalogued as rs747536589; called by muse, mutect2, varscan2
- MAGEA12 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 203/354 reads (57%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.971); catalogued as COSV63295564; called by muse, mutect2, varscan2
- MAN2B1 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 89/232 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs774034389, CM124082; ClinVar: uncertain significance; called by muse, mutect2
- MAP7D1 | c.2504C>T p.P835L | Missense Mutation (SNP) | VAF 209/340 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs768559148; called by muse, mutect2, varscan2
- MAST1 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 63/299 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768167266; called by muse, mutect2, varscan2
- MCTP1 | c.1796C>T p.S599F | Missense Mutation (SNP) | VAF 141/224 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as COSV56534695; called by muse, mutect2, varscan2
- MGAM2 | c.5050C>T p.R1684* | Nonsense Mutation (SNP) | VAF 68/193 reads (35%) | catalogued as rs1271423734; called by muse, mutect2, varscan2
- MINDY4 | c.1967G>T p.C656F | Missense Mutation (SNP) | VAF 219/403 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV54672874; called by muse, mutect2, varscan2
- MLF2 | c.326C>A p.S109Y | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52570872; called by muse, mutect2, varscan2
- MUC13 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 45/243 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs373312041, COSV60700053; called by muse, mutect2, varscan2
- MUC16 | c.3264G>A p.M1088I | Missense Mutation (SNP) | VAF 184/372 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs756526885; called by muse, mutect2, varscan2
- MUC5B | c.15508G>A p.G5170S | Missense Mutation (SNP) | VAF 83/356 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.339); catalogued as rs530544887, COSV101500555; called by muse, mutect2, varscan2
- MYH3 | c.5599G>A p.D1867N | Missense Mutation (SNP) | VAF 57/253 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as COSV56865573; called by muse, mutect2, varscan2
- MYH4 | c.3170G>A p.R1057K | Missense Mutation (SNP) | VAF 96/211 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as COSV55115585; called by muse, mutect2, varscan2
- MYO7A | c.6248C>T p.A2083V | Missense Mutation (SNP) | VAF 119/267 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.164); catalogued as rs996456366, COSV60017160; called by muse, mutect2, varscan2
- NBEA | c.6704C>T p.T2235I | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs528630327, COSV59794746; called by muse, mutect2, varscan2
- NFX1 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 123/371 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.051); catalogued as COSV100581758; called by muse, mutect2, varscan2
- NLRP12 | c.2968C>T p.L990F | Missense Mutation (SNP) | VAF 64/311 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100146177; called by muse, mutect2, varscan2
- OGFOD3 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 268/380 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs375729780; called by muse, mutect2, varscan2
- OR14C36 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 65/491 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV58602821; called by muse, mutect2, varscan2
- OR1N2 | c.700C>A p.P234T | Missense Mutation (SNP) | VAF 107/373 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.023); catalogued as COSV101031354; called by mutect2, varscan2
- OR51B2 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 62/293 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1299360359, COSV60916055, COSV60917267; called by muse, mutect2, varscan2
- OR52N5 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 98/142 reads (69%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV57698645; called by muse, mutect2, varscan2
- OR5D18 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376041728, COSV100450973; called by muse, mutect2, varscan2
- PABPN1L | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 248/525 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1486304107; called by muse, mutect2, varscan2
- PAFAH1B1 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 138/295 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV68210666; called by muse, mutect2, varscan2
- PALB2 | c.2606C>T p.S869F | Missense Mutation (SNP) | VAF 53/249 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779279139, CM1512724, COSV55165901; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PAPPA2 | c.1739G>A p.R580Q | Missense Mutation (SNP) | VAF 290/523 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs777147973, COSV62783931; called by muse, mutect2, varscan2
- PAX2 | c.76G>A p.V26M | Missense Mutation (SNP) | VAF 100/374 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs1022509510, CD992538, COSV62291971; called by muse, mutect2, varscan2
- PAXBP1 | c.1487C>T p.S496L | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs1229809110, COSV51611863; called by muse, mutect2, varscan2
- PCDH12 | c.2662G>A p.G888R | Missense Mutation (SNP) | VAF 44/477 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.025); catalogued as COSV51523572; called by muse, mutect2
- PCDHB6 | c.1499C>T p.S500F | Missense Mutation (SNP) | VAF 19/649 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50693564; called by muse, mutect2
- PCDHB7 | c.772G>A p.G258S | Missense Mutation (SNP) | VAF 31/280 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as COSV50754229; called by muse, mutect2, varscan2
- PCED1A | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 188/519 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs147321844; called by muse, mutect2, varscan2
- PKP4 | c.2105C>T p.S702F | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100733843; called by muse, mutect2, varscan2
- POLR2F | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 77/404 reads (19%) | catalogued as rs1344090517; called by muse, mutect2, varscan2
- POLRMT | c.2249C>T p.A750V | Missense Mutation (SNP) | VAF 253/565 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs1248940235; called by muse, mutect2, varscan2
- POTEH | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 268/1079 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs747485524, COSV58881978; called by muse, mutect2, varscan2
- PRM1 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 126/321 reads (39%) | PolyPhen possibly damaging (0.873); catalogued as rs756022923, COSV54113583; called by muse, mutect2, varscan2
- PROX1 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 186/468 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV54783865; called by muse, mutect2, varscan2
- PSG8 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 146/322 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs142736244; called by muse, mutect2, varscan2
- PSG9 | c.1162C>T p.H388Y | Missense Mutation (SNP) | VAF 188/391 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV52484024; called by muse, mutect2, varscan2
- PTPRD | c.4939G>A p.E1647K | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766088715, COSV61937509; called by muse, mutect2, varscan2
- PTPRK | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 90/143 reads (63%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.489); catalogued as rs757490289, COSV63888355; called by muse, mutect2, varscan2
- RAD9A | c.670-1G>A p.X224_splice | Splice Site (SNP) | VAF 107/207 reads (52%) | catalogued as rs1396965903; called by muse, mutect2, varscan2
- RB1 | c.829C>T p.L277F | Missense Mutation (SNP) | VAF 88/220 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57307919; called by muse, mutect2, varscan2
- RB1CC1 | c.1825C>T p.H609Y | Missense Mutation (SNP) | VAF 83/347 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as rs766946770; called by muse, mutect2, varscan2
- RGS7 | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 50/347 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV100472121; called by muse, mutect2, varscan2
- RIMS2 | c.1364G>A p.R455Q (on ENST00000666250 / NM_001348490.2; = p.R263Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 185/721 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.969); catalogued as COSV51653092; called by muse, mutect2, varscan2
- RP1 | c.2461C>T p.H821Y | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.637); catalogued as COSV55111203; called by muse, mutect2, varscan2
- RP1L1 | c.1631G>A p.G544E | Missense Mutation (SNP) | VAF 129/546 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1205062318; called by muse, mutect2, varscan2
- RTL1 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 230/462 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); catalogued as rs868083594; called by muse, mutect2, varscan2
- SCN10A | c.2767C>T p.R923C | Missense Mutation (SNP) | VAF 217/435 reads (50%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.713); catalogued as rs267599803; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN1A | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 73/345 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57685284; called by muse, mutect2, varscan2
- SELP | c.1634C>T p.S545F | Missense Mutation (SNP) | VAF 87/462 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.222); catalogued as rs1349645726; called by muse, mutect2, varscan2
- SI | c.5312C>T p.S1771F | Missense Mutation (SNP) | VAF 114/204 reads (56%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs759478116, COSV52272153; called by muse, mutect2, varscan2
- SIGLEC10 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 49/208 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs747638044, COSV59486819; called by muse, mutect2, varscan2
- SIPA1L2 | c.3479C>T p.P1160L | Missense Mutation (SNP) | VAF 73/558 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs1406639665; called by muse, mutect2, varscan2
- SLC39A14 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 118/498 reads (24%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV51484801; called by muse, mutect2
- SLX4 | c.4043C>T p.P1348L | Missense Mutation (SNP) | VAF 107/533 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV53568595; called by muse, mutect2, varscan2
- SMR3A | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 80/290 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.758); catalogued as COSV56950234; called by muse, mutect2, varscan2
- SOX10 | c.254G>A p.W85* | Nonsense Mutation (SNP) | VAF 102/539 reads (19%) | catalogued as CM113191; called by muse, mutect2, varscan2
- SOX17 | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 89/875 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs754601531, COSV99810831; called by muse, mutect2, varscan2
- SPAG17 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60452821; called by muse, mutect2, varscan2
- SPATA31A1 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 120/500 reads (24%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.878); catalogued as rs1370894649; called by muse, varscan2
- SPATA31A7 | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 275/593 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs777585378; called by muse, mutect2, varscan2
- SPATA5L1 | c.1343C>T p.S448L | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.087); catalogued as rs370961171; called by muse, mutect2, varscan2
- SPTBN4 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 141/338 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs577893580; called by muse, mutect2, varscan2
- STXBP5L | c.2543C>T p.T848I | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.08); catalogued as rs1560040800; called by muse, mutect2, varscan2
- SYNE1 | c.22286G>A p.R7429K (on ENST00000367255 / NM_182961.4; = p.R7358K on NM_033071.3) | Missense Mutation (SNP) | VAF 120/206 reads (58%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV54987249; called by muse, mutect2, varscan2
- THSD7A | c.4067C>T p.A1356V | Missense Mutation (SNP) | VAF 103/309 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.163); catalogued as rs778209809, COSV101439751; called by muse, mutect2, varscan2
- THSD7B | c.3538G>A p.E1180K (on ENST00000272643; = p.E1178K on NM_001316349.2) | Missense Mutation (SNP) | VAF 149/323 reads (46%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.699); catalogued as COSV55655747, COSV99742785; called by muse, mutect2, varscan2
- TIAM2 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 151/271 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.854); catalogued as rs747297698; called by muse, mutect2, varscan2
- TIE1 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 200/432 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as rs1243488598; called by muse, varscan2
- TJP1 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs377439498; called by muse, mutect2, varscan2
- TLR2 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 72/305 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1560755641; called by muse, mutect2, varscan2
- TMEM132B | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 149/272 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0.23); catalogued as COSV54774404, COSV54774594; called by muse, mutect2, varscan2
- TMPRSS2 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 121/487 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as rs762928261; called by muse, mutect2, varscan2
- TRIM56 | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 215/585 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs201997747; called by muse, mutect2, varscan2
- TRIP11 | c.5761C>T p.P1921S | Missense Mutation (SNP) | VAF 62/269 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as COSV50913542; called by muse, mutect2, varscan2
- TTC39C | c.803C>T p.A268V (on ENST00000317571 / NM_001135993.2; = p.A207V on NM_153211.4) | Missense Mutation (SNP) | VAF 86/266 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238923519; called by muse, mutect2, varscan2
- TTN | c.28501G>A p.E9501K (on ENST00000591111; = p.E8574K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/134 reads (51%) | PolyPhen possibly damaging (0.572); catalogued as COSV60181762; called by muse, mutect2, varscan2
- TTN | c.25370G>A p.G8457E (on ENST00000591111; = p.G7530E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 156/353 reads (44%) | PolyPhen benign (0.009); catalogued as COSV60419536; called by muse, mutect2, varscan2
- TTN | c.2995C>T p.R999C (on ENST00000591111; = p.R953C on NM_003319.4) | Missense Mutation (SNP) | VAF 166/408 reads (41%) | PolyPhen probably damaging (0.966); catalogued as rs142000511; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC13C | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 129/288 reads (45%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV52843804; called by muse, mutect2, varscan2
- VPS13D | c.2161C>T p.P721S | Missense Mutation (SNP) | VAF 116/291 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.206); catalogued as rs1477037676, COSV50633307; called by muse, mutect2, varscan2
- WDFY4 | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 99/316 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs865793313; called by muse, mutect2, varscan2
- WDR35 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV55602907; called by muse, mutect2, varscan2
- WIPF3 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 126/386 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.997); catalogued as rs1214565948; called by muse, mutect2, varscan2
- XIRP2 | c.5893C>T p.H1965Y (on ENST00000628543; = p.H2140Y on NM_152381.6) | Missense Mutation (SNP) | VAF 64/261 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs866971820; called by muse, mutect2, varscan2
- XPC | c.1973C>T p.A658V | Missense Mutation (SNP) | VAF 75/403 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV53204340; called by muse, mutect2, varscan2
- ZNF284 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69690796; called by muse, mutect2, varscan2
- ZNF423 | c.3379G>A p.G1127S (on ENST00000563137 / NM_001379286.1; = p.G1119S on NM_015069.4) | Missense Mutation (SNP) | VAF 139/567 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.015); catalogued as rs146352545, COSV99282059; called by muse, mutect2, varscan2
- ZNF496 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 130/672 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.76); catalogued as COSV99665133; called by muse, mutect2, varscan2
- ZNF534 | c.1501C>T p.H501Y (on ENST00000332323 / NM_001143939.3; = p.H488Y on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 155/374 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs758829376, COSV56517383; called by muse, mutect2, varscan2
- ZNF594 | c.676C>T p.L226F | Missense Mutation (SNP) | VAF 142/326 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as rs1384361012; called by muse, mutect2, varscan2
- ZNF669 | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 115/660 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs771458579, COSV100594300; called by muse, mutect2, varscan2
- ZNF676 | c.1339C>T p.H447Y (on ENST00000650058; = p.H415Y on NM_001001411.3) | Missense Mutation (SNP) | VAF 98/455 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV68092789; called by muse, mutect2, varscan2
- ZNF682 | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as COSV62066912; called by muse, mutect2, varscan2
- A1CF | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ABCC8 | c.2902G>A p.D968N | Missense Mutation (SNP) | VAF 72/333 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- AC008687.4 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 217/420 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- AC098582.1 | c.1931C>T p.S644F | Missense Mutation (SNP) | VAF 81/156 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- ACKR4 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 117/411 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS10 | c.2865G>A p.E955= | Splice Region (SNP) | VAF 191/392 reads (49%) | called by muse, mutect2, varscan2
- ADCY4 | c.2722G>A p.D908N | Missense Mutation (SNP) | VAF 107/270 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ADGRA2 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 55/237 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- ADGRG3 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 66/289 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- ADGRG7 | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRL2 | c.1655G>A p.G552E | Missense Mutation (SNP) | VAF 156/365 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- AGL | c.929T>C p.V310A | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2
- AGT | c.1351G>A p.V451I | Missense Mutation (SNP) | VAF 274/494 reads (55%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD62 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 83/322 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- ASAP3 | c.59C>A p.S20Y | Missense Mutation (SNP) | VAF 92/441 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ASTE1 | c.351A>C p.L117F | Missense Mutation (SNP) | VAF 132/265 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ASXL3 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 150/393 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- B3GNT8 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 147/625 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BCAN | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 409/743 reads (55%) | SIFT tolerated (0.27); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- BCAT2 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 53/338 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1QTNF9 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 67/616 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- C1QTNF9B | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- C20orf194 | c.2743C>T p.P915S | Missense Mutation (SNP) | VAF 174/467 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNA1E | c.6076G>A p.D2026N (on ENST00000367573 / NM_001205293.3; = p.D1983N on NM_000721.4) | Missense Mutation (SNP) | VAF 95/446 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- CCDC105 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 207/441 reads (47%) | SIFT tolerated (0.96); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC173 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- CCDC18 | c.797T>C p.V266A | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- CD96 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 74/347 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CEACAM20 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 159/345 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CEP44 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- CLPTM1L | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 209/326 reads (64%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL6A3 | c.9049C>T p.P3017S | Missense Mutation (SNP) | VAF 136/323 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL8A2 | c.1255C>A p.P419T | Missense Mutation (SNP) | VAF 115/676 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- COQ8B | c.1570C>A p.Q524K | Missense Mutation (SNP) | VAF 217/503 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CPNE8 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 43/61 reads (70%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CSMD1 | c.5242C>T p.P1748S (on ENST00000520002; = p.P1747S on NM_033225.6) | Missense Mutation (SNP) | VAF 140/308 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTNNA3 | c.2014A>T p.K672* | Nonsense Mutation (SNP) | VAF 41/133 reads (31%) | called by muse, mutect2, varscan2
- CTPS1 | c.173T>C p.V58A | Missense Mutation (SNP) | VAF 48/236 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DDX60 | c.2260G>A p.D754N | Missense Mutation (SNP) | VAF 49/268 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- DGKI | c.679A>T p.K227* | Nonsense Mutation (SNP) | VAF 78/260 reads (30%) | called by muse, mutect2, varscan2
- DHODH | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 182/430 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- DNAH11 | c.13523C>T p.A4508V | Missense Mutation (SNP) | VAF 71/464 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH2 | c.2986G>A p.E996K | Missense Mutation (SNP) | VAF 140/279 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- DNAH6 | c.5701G>A p.E1901K | Missense Mutation (SNP) | VAF 72/195 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DUOX1 | c.3170G>A p.G1057E | Missense Mutation (SNP) | VAF 132/272 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- EHD3 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 138/322 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF2B3 | c.1292G>A p.R431K | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ELFN2 | c.1813C>A p.P605T | Missense Mutation (SNP) | VAF 172/394 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- EML6 | c.2573G>A p.G858E | Missense Mutation (SNP) | VAF 47/268 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- ENKUR | c.370A>T p.I124F | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- EPHA10 | c.2606G>A p.R869K | Missense Mutation (SNP) | VAF 84/450 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ETV3L | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 278/494 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM107A | c.52C>T p.H18Y | Missense Mutation (SNP) | VAF 116/279 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FAM13A | c.2570C>T p.P857L | Missense Mutation (SNP) | VAF 65/285 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- FAM184B | c.2693G>A p.G898E | Missense Mutation (SNP) | VAF 103/240 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- FAM71A | c.1782T>A p.H594Q | Missense Mutation (SNP) | VAF 143/267 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2
- FAM83B | c.563T>A p.F188Y | Missense Mutation (SNP) | VAF 76/264 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FANCE | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 240/727 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- FBN1 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 158/339 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FLG | c.9254G>A p.G3085E | Missense Mutation (SNP) | VAF 268/567 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- FMN2 | c.3443G>A p.R1148K | Missense Mutation (SNP) | VAF 27/205 reads (13%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- FMO4 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 318/548 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FSD1 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 166/374 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- GALNT16 | c.299G>A p.S100N | Missense Mutation (SNP) | VAF 160/415 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- GDAP1 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 382/685 reads (56%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GDI2 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GNAS | c.1126T>C p.F376L | Missense Mutation (SNP) | VAF 162/429 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIA4 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 202/392 reads (52%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- GSDMA | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 63/248 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- HAP1 | c.1486A>G p.R496G (on ENST00000310778 / NM_001367460.1; = p.R444G on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/347 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- HAUS5 | c.937_939del p.K313del | In Frame Del (DEL) | VAF 110/494 reads (22%) | called by mutect2, pindel, varscan2
- HELZ2 | c.7503C>T p.V2501= (on ENST00000467148 / NM_001037335.2; = p.V1932= on NM_033405.3) | Splice Region (SNP) | VAF 115/331 reads (35%) | called by muse, mutect2, varscan2
- HOMER1 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXC9 | c.232C>G p.H78D | Missense Mutation (SNP) | VAF 18/512 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- HYDIN | c.14227C>T p.P4743S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.155); called by mutect2, varscan2
- IGHV1-46 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 45/195 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- IGHV3-66 | c.46G>C p.G16R | Missense Mutation (SNP) | VAF 70/337 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- IQCM | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ITGAE | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 195/427 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITGAM | c.1859G>A p.R620K (on ENST00000648685 / NM_001145808.2; = p.R619K on NM_000632.4) | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ITGB1 | c.2272C>T p.H758Y | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITIH1 | c.239A>T p.N80I | Missense Mutation (SNP) | VAF 158/326 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by mutect2, varscan2
- KCNH6 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 740/1010 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- KCNJ6 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 215/437 reads (49%) | SIFT tolerated (0.53); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- KIF15 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 154/343 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KIF1B | c.4102T>A p.S1368T (on ENST00000377086 / NM_001365952.1; = p.S1322T on NM_015074.3) | Missense Mutation (SNP) | VAF 152/372 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, mutect2
- KIF5A | c.2240C>T p.A747V | Missense Mutation (SNP) | VAF 91/174 reads (52%) | SIFT tolerated (0.47); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KIR2DL1 | c.541T>A p.F181I | Missense Mutation (SNP) | VAF 67/399 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- KLHL4 | c.934A>T p.I312F | Missense Mutation (SNP) | VAF 93/139 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- LGALS12 | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 157/355 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LILRA5 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 124/532 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- LIPE | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 54/265 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- LIPJ | c.1057C>T p.Q353* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- LLGL2 | c.2843G>A p.G948D | Missense Mutation (SNP) | VAF 554/769 reads (72%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LMOD2 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 205/504 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LMTK3 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 61/322 reads (19%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- LOXL2 | c.1494T>A p.D498E | Missense Mutation (SNP) | VAF 159/328 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRP1 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 145/262 reads (55%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEB6B | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 223/372 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- MAGEL2 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 120/563 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MANSC4 | c.434G>A p.R145K | Missense Mutation (SNP) | VAF 93/158 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MEF2B | c.1016G>A p.S339N | Missense Mutation (SNP) | VAF 258/543 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, varscan2
- METRN | c.512G>T p.C171F | Missense Mutation (SNP) | VAF 95/376 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- MFHAS1 | c.1702G>A p.G568R | Missense Mutation (SNP) | VAF 103/565 reads (18%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- MGAM2 | c.2758G>A p.D920N | Missense Mutation (SNP) | VAF 143/432 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- MINDY4B | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MIOS | c.2510G>A p.G837E | Missense Mutation (SNP) | VAF 159/344 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- MLLT6 | c.1783C>T p.P595S | Missense Mutation (SNP) | VAF 141/555 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MTARC1 | c.131G>A p.W44* | Nonsense Mutation (SNP) | VAF 328/614 reads (53%) | called by muse, mutect2, varscan2
- MTBP | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC16 | c.34258C>T p.P11420S | Missense Mutation (SNP) | VAF 76/302 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- MUC16 | c.30604G>A p.D10202N | Missense Mutation (SNP) | VAF 154/355 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MUC16 | c.19947G>A p.M6649I | Missense Mutation (SNP) | VAF 203/420 reads (48%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MYBPC2 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 108/306 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYH2 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 84/331 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- MYH7 | c.2925G>A p.V975= | Splice Region (SNP) | VAF 63/218 reads (29%) | called by muse, mutect2
- MYOM3 | c.1867G>A p.D623N | Missense Mutation (SNP) | VAF 165/396 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NANOGP8 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 201/593 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.068); called by muse, varscan2
- NEB | c.13699G>A p.E4567K | Missense Mutation (SNP) | VAF 133/280 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NLGN2 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 93/390 reads (24%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NOXA1 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 121/215 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- NPNT | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 124/261 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- NUAK2 | c.1231C>T p.L411F | Missense Mutation (SNP) | VAF 284/520 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- OR52K2 | c.883G>A p.G295S | Missense Mutation (SNP) | VAF 149/315 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- OR5H6 | c.758C>T p.A253V (on ENST00000642105; = p.A237V on NM_001005479.2) | Missense Mutation (SNP) | VAF 71/191 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- OR6K6 | c.688C>T p.H230Y (on ENST00000368144; = p.H206Y on NM_001005184.1) | Missense Mutation (SNP) | VAF 317/583 reads (54%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OTOA | c.1613G>A p.R538K (on ENST00000286149; = p.R524K on NM_144672.4) | Missense Mutation (SNP) | VAF 126/251 reads (50%) | SIFT tolerated (0.99); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- OTX1 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 117/498 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- PALD1 | c.2494C>T p.P832S | Missense Mutation (SNP) | VAF 91/355 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- PARP6 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 158/350 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAX1 | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 119/326 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- PCDH11X | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 184/312 reads (59%) | SIFT tolerated (0.91); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDHB1 | c.685C>T p.H229Y | Missense Mutation (SNP) | VAF 34/354 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHB11 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 180/328 reads (55%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- PCDHGA3 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 182/317 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- PIPOX | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 135/298 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- PKDREJ | c.2436G>A p.M812I | Missense Mutation (SNP) | VAF 99/315 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PLCB1 | c.749A>G p.N250S | Missense Mutation (SNP) | VAF 91/277 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- POF1B | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 55/84 reads (65%) | called by muse, mutect2, varscan2
- POLQ | c.6806C>T p.P2269L | Missense Mutation (SNP) | VAF 89/239 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- POM121L2 | c.228G>A p.W76* | Nonsense Mutation (SNP) | VAF 246/734 reads (34%) | called by muse, mutect2
- POU2F1 | c.1000C>T p.L334F (on ENST00000541643 / NM_001365848.1; = p.L357F on NM_002697.4) | Missense Mutation (SNP) | VAF 54/343 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POU5F2 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 212/402 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- PPARG | c.83-1G>A p.X28_splice | Splice Site (SNP) | VAF 120/236 reads (51%) | called by muse, mutect2, varscan2
- PPARG | c.1426G>A p.E476K (on ENST00000287820 / NM_015869.5; = p.E446K on NM_005037.7) | Missense Mutation (SNP) | VAF 59/353 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- PRCC | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 87/546 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PRCC | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 86/549 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- PRDM10 | c.649T>C p.F217L | Missense Mutation (SNP) | VAF 101/484 reads (21%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RAG1 | c.554G>A p.R185K | Missense Mutation (SNP) | VAF 186/460 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RASGRF2 | c.3093G>A p.W1031* | Nonsense Mutation (SNP) | VAF 107/185 reads (58%) | called by muse, mutect2, varscan2
- RBBP8NL | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 233/638 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- RBP7 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 134/286 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RNASEH2A | c.164C>G p.P55R | Missense Mutation (SNP) | VAF 179/709 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RNF213 | c.3433G>A p.E1145K | Missense Mutation (SNP) | VAF 457/633 reads (72%) | SIFT tolerated (0.43); PolyPhen benign (0.005); called by muse, mutect2
- RYR1 | c.5958G>A p.M1986I | Missense Mutation (SNP) | VAF 165/367 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- SCARA3 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 147/321 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SCN1A | c.3359G>A p.G1120E (on ENST00000303395 / NM_001202435.3; = p.G1109E on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- SCRIB | c.4048G>A p.E1350K | Missense Mutation (SNP) | VAF 256/1073 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SETD2 | c.6148C>T p.Q2050* | Nonsense Mutation (SNP) | VAF 66/284 reads (23%) | called by muse, mutect2, varscan2
- SLC25A23 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 102/430 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- SLC4A2 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 103/600 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC6A14 | c.1909G>A p.G637S | Missense Mutation (SNP) | VAF 83/144 reads (58%) | SIFT tolerated (0.24); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SLIT1 | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 79/257 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLK | c.18C>A p.F6L | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SNAP91 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 134/193 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SNX20 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 203/437 reads (46%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SOAT1 | c.697G>T p.G233* | Nonsense Mutation (SNP) | VAF 52/383 reads (14%) | called by muse, mutect2, varscan2
- SOWAHB | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 226/482 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SOX14 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 205/441 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPTB | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 92/418 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SSU72P3 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 86/431 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.952); called by muse, mutect2
- STK36 | c.1873C>T p.H625Y | Missense Mutation (SNP) | VAF 156/347 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SUPT5H | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- SYT13 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 107/521 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- SYT5 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 105/446 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- TARBP1 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 130/852 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAS2R60 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 166/467 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TBC1D2B | c.2567G>A p.G856E | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TCTE1 | c.1425A>T p.E475D | Missense Mutation (SNP) | VAF 226/608 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TECPR2 | c.3046C>T p.P1016S | Missense Mutation (SNP) | VAF 128/263 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEX26 | c.378G>T p.W126C | Missense Mutation (SNP) | VAF 151/335 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- THOC2 | c.2431C>T p.H811Y | Missense Mutation (SNP) | VAF 130/230 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- TIAL1 | c.168T>A p.Y56* | Nonsense Mutation (SNP) | VAF 55/162 reads (34%) | called by muse, varscan2
- TMEM225B | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 132/447 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- TMEM245 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 139/210 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- TNFRSF25 | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 202/426 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TNMD | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 120/210 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TNRC6B | c.2856G>A p.W952* (on ENST00000454349 / NM_001162501.2; = p.W205* on NM_001024843.1) | Nonsense Mutation (SNP) | VAF 86/361 reads (24%) | called by muse, mutect2, varscan2
- TRAV30 | c.273A>C p.Q91H | Missense Mutation (SNP) | VAF 129/241 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TRBC2 | c.513G>A p.M171I | Missense Mutation (SNP) | VAF 121/326 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- TRBV6-1 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 97/304 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- TRIM7 | c.1190A>G p.H397R | Missense Mutation (SNP) | VAF 248/476 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TSGA10IP | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 76/411 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- TSGA10IP | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 77/408 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TSPYL6 | c.787T>G p.S263A | Missense Mutation (SNP) | VAF 73/369 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- UBD | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 260/695 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- USH2A | c.11441G>A p.G3814E | Missense Mutation (SNP) | VAF 44/270 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); called by muse, varscan2
- USP24 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VWDE | c.2147G>A p.G716E | Missense Mutation (SNP) | VAF 118/482 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WAPL | c.1478A>G p.E493G | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- XRRA1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 85/195 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ZBTB22 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 330/803 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZBTB37 | c.757T>G p.W253G | Missense Mutation (SNP) | VAF 282/496 reads (57%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZFP41 | c.360C>G p.C120W | Missense Mutation (SNP) | VAF 577/983 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF107 | c.1204C>T p.H402Y | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- ZNF397 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 152/386 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF502 | c.1250T>C p.I417T | Missense Mutation (SNP) | VAF 93/430 reads (22%) | SIFT tolerated (0.91); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZNF536 | c.1480C>T p.L494F | Missense Mutation (SNP) | VAF 219/495 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF560 | c.2269C>T p.Q757* | Nonsense Mutation (SNP) | VAF 215/421 reads (51%) | called by muse, mutect2, varscan2
- ZNF713 | c.41G>A p.R14K (on ENST00000633730 / NM_001366796.2; = p.R27K on NM_182633.3) | Missense Mutation (SNP) | VAF 106/476 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCC8 | c.2901G>A p.Q967= | Silent (SNP) | VAF 72/337 reads (21%) | called by muse, mutect2, varscan2
- AC010325.1 | c.27C>T p.S9= | Silent (SNP) | VAF 153/305 reads (50%) | catalogued as rs1399657698; called by muse, mutect2, varscan2
- ACOT4 | c.411G>A p.Q137= | Silent (SNP) | VAF 96/386 reads (25%) | called by muse, mutect2, varscan2
- ADAM29 | c.1728C>T p.F576= | Silent (SNP) | VAF 93/384 reads (24%) | catalogued as COSV100822047; called by muse, mutect2, varscan2
- ADAMTS6 | c.2091G>A p.L697= | Silent (SNP) | VAF 24/256 reads (9%) | called by muse, mutect2
- ADCY2 | c.513C>T p.I171= | Silent (SNP) | VAF 40/466 reads (9%) | catalogued as rs752304266, COSV57895529; called by muse, mutect2
- ADGRA2 | c.1089G>T p.G363= | Silent (SNP) | VAF 56/239 reads (23%) | catalogued as COSV59443492; called by muse, mutect2, varscan2
- ADGRV1 | c.12234G>A p.E4078= | Silent (SNP) | VAF 161/270 reads (60%) | called by muse, mutect2, varscan2
- ADH1A | c.816G>A p.R272= | Silent (SNP) | VAF 59/291 reads (20%) | called by muse, mutect2, varscan2
- AHCTF1 | c.4563A>G p.L1521= (on ENST00000366508; = p.L1495= on NM_015446.5) | Silent (SNP) | VAF 160/361 reads (44%) | called by muse, mutect2, varscan2
- AHNAK2 | c.9399C>T p.D3133= | Silent (SNP) | VAF 127/690 reads (18%) | called by muse, mutect2, varscan2
- ALAS1 | c.1239C>T p.V413= | Silent (SNP) | VAF 178/354 reads (50%) | called by muse, mutect2, varscan2
- ALDH2 | c.1515G>A p.V505= | Silent (SNP) | VAF 107/195 reads (55%) | catalogued as rs569388000; called by muse, varscan2
- ANKRD17 | c.3270C>T p.A1090= | Silent (SNP) | VAF 123/281 reads (44%) | catalogued as rs1186560795; called by muse, mutect2, varscan2
- ANKRD24 | c.1275C>T p.A425= | Silent (SNP) | VAF 159/320 reads (50%) | catalogued as rs539092814; called by muse, mutect2
- ANKS1B | c.2004G>A p.V668= | Silent (SNP) | VAF 184/301 reads (61%) | catalogued as rs947695641, COSV61350287; called by muse, mutect2, varscan2
- APBB1IP | c.501G>A p.L167= | Silent (SNP) | VAF 54/200 reads (27%) | catalogued as COSV63304597; called by muse, mutect2, varscan2
- APOL6 | c.915G>A p.K305= | Silent (SNP) | VAF 205/541 reads (38%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.795C>T p.I265= | Silent (SNP) | VAF 143/220 reads (65%) | catalogued as rs892775801, COSV52450702; called by muse, mutect2, varscan2
- ARHGAP22 | c.255G>A p.G85= | Silent (SNP) | VAF 55/234 reads (24%) | called by muse, mutect2, varscan2
- ARHGEF16 | c.1749C>T p.F583= | Silent (SNP) | VAF 103/462 reads (22%) | called by muse, mutect2, varscan2
- ARL16 | c.27G>A p.L9= | Silent (SNP) | VAF 74/766 reads (10%) | catalogued as rs769963539, COSV61266634, COSV61267465; called by muse, mutect2, varscan2
- B3GNT9 | c.684C>T p.G228= | Silent (SNP) | VAF 120/451 reads (27%) | catalogued as COSV54628500; called by muse, mutect2, varscan2
- BCL7B | c.381C>T p.S127= | Silent (SNP) | VAF 226/568 reads (40%) | catalogued as rs782483081; called by muse, mutect2, varscan2
- BMP2 | c.378G>A p.G126= | Silent (SNP) | VAF 68/184 reads (37%) | catalogued as rs904725474, COSV66579396; called by muse, mutect2, varscan2
- BPIFA2 | c.306G>A p.L102= | Silent (SNP) | VAF 91/261 reads (35%) | called by muse, mutect2, varscan2
- CACNA1A | c.1554C>T p.F518= | Silent (SNP) | VAF 37/208 reads (18%) | catalogued as COSV64210000; called by muse, mutect2, varscan2
- CACNA1B | c.411C>T p.F137= | Silent (SNP) | VAF 141/229 reads (62%) | catalogued as COSV53127963; called by muse, mutect2, varscan2
- CARD11 | c.2568G>A p.E856= | Silent (SNP) | VAF 163/701 reads (23%) | called by muse, mutect2, varscan2
- CASR | c.87G>A p.K29= | Silent (SNP) | VAF 78/449 reads (17%) | catalogued as rs868678822; called by muse, mutect2, varscan2
- CC2D1B | c.678C>T p.A226= | Silent (SNP) | VAF 107/506 reads (21%) | called by muse, mutect2, varscan2
- CCDC88B | c.4140C>T p.S1380= | Silent (SNP) | VAF 216/467 reads (46%) | catalogued as COSV53702222; called by muse, mutect2, varscan2
- CD244 | c.432G>A p.K144= (on ENST00000368033 / NM_001166663.2; = p.K139= on NM_016382.4) | Silent (SNP) | VAF 83/479 reads (17%) | catalogued as COSV100458206; called by muse, mutect2, varscan2
- CDH23 | c.9843G>A p.G3281= | Silent (SNP) | VAF 100/358 reads (28%) | called by muse, mutect2, varscan2
- CEP72 | c.987C>T p.P329= | Silent (SNP) | VAF 287/438 reads (66%) | catalogued as rs553435382, COSV53795804; called by muse, mutect2, varscan2
- CFAP57 | c.2736A>G p.E912= | Silent (SNP) | VAF 114/282 reads (40%) | called by muse, mutect2, varscan2
- CLVS1 | c.486C>T p.I162= | Silent (SNP) | VAF 124/557 reads (22%) | catalogued as rs1047653172; called by muse, mutect2, varscan2
- COL24A1 | c.2481G>A p.K827= | Silent (SNP) | VAF 46/147 reads (31%) | catalogued as rs1465556219, COSV65308379, COSV65314427; called by muse, mutect2, varscan2
- COL4A1 | c.2376C>T p.S792= | Silent (SNP) | VAF 132/365 reads (36%) | catalogued as rs535938031, COSV65422537; called by muse, mutect2, varscan2
- COQ8A | c.789C>T p.I263= | Silent (SNP) | VAF 97/522 reads (19%) | catalogued as rs375123701; ClinVar: likely benign; called by muse, mutect2, varscan2
- CPED1 | c.117G>A p.R39= | Silent (SNP) | VAF 153/405 reads (38%) | called by muse, mutect2, varscan2
- CPT1C | c.945G>A p.R315= | Silent (SNP) | VAF 60/288 reads (21%) | catalogued as COSV54917654; called by muse, mutect2, varscan2
- CRP | c.507C>T p.S169= | Silent (SNP) | VAF 93/494 reads (19%) | called by muse, mutect2, varscan2
- CTDSPL2 | c.678C>A p.I226= | Silent (SNP) | VAF 38/182 reads (21%) | catalogued as rs750460927; called by muse, mutect2, varscan2
- CUEDC1 | c.765C>T p.F255= | Silent (SNP) | VAF 72/592 reads (12%) | called by muse, mutect2, varscan2
- CYFIP1 | c.609C>T p.S203= | Silent (SNP) | VAF 56/297 reads (19%) | catalogued as rs1357339194; called by muse, mutect2, varscan2
- CYYR1 | c.270C>T p.N90= | Silent (SNP) | VAF 64/374 reads (17%) | catalogued as rs776790380; called by muse, mutect2, varscan2
- DACH1 | c.631C>T p.L211= | Silent (SNP) | VAF 182/390 reads (47%) | called by muse, mutect2, varscan2
- DCDC1 | c.3432G>A p.V1144= (on ENST00000597505 / NM_001367979.1; = p.V251= on NM_020869.3) | Silent (SNP) | VAF 106/242 reads (44%) | catalogued as COSV100337707, COSV60304035; called by muse, mutect2, varscan2
- DCHS2 | c.1470C>T p.F490= | Silent (SNP) | VAF 261/505 reads (52%) | catalogued as COSV59719266; called by muse, mutect2, varscan2
- DNAH1 | c.606G>A p.L202= | Silent (SNP) | VAF 140/346 reads (40%) | catalogued as rs1300166141; called by muse, mutect2, varscan2
- DNAH1 | c.8970C>T p.G2990= | Silent (SNP) | VAF 64/306 reads (21%) | called by muse, mutect2, varscan2
- DNAH17 | c.6252G>A p.R2084= | Silent (SNP) | VAF 250/357 reads (70%) | catalogued as COSV67750663; called by muse, mutect2, varscan2
- DNAH3 | c.10011G>A p.T3337= | Silent (SNP) | VAF 143/331 reads (43%) | catalogued as rs367808003; called by muse, mutect2, varscan2
- DOT1L | c.3846C>T p.P1282= | Silent (SNP) | VAF 126/609 reads (21%) | called by muse, mutect2, varscan2
- DTX2 | c.1803C>T p.Y601= | Silent (SNP) | VAF 243/658 reads (37%) | called by muse, mutect2, varscan2
- DUOX2 | c.3102C>T p.F1034= | Silent (SNP) | VAF 86/427 reads (20%) | catalogued as rs768010975, COSV66531430; called by muse, mutect2, varscan2
- EFNA5 | c.652C>T p.L218= | Silent (SNP) | VAF 143/271 reads (53%) | catalogued as rs1461695228, COSV100321232; called by muse, mutect2, varscan2
- EPS15 | c.1326T>C p.T442= | Silent (SNP) | VAF 238/438 reads (54%) | catalogued as COSV100869378; called by muse, mutect2
- ERCC2 | c.1443C>T p.F481= | Silent (SNP) | VAF 164/317 reads (52%) | catalogued as rs753890075; called by muse, mutect2, varscan2
- EXD2 | c.1758C>T p.F586= (on ENST00000312994 / NM_001193362.1; = p.F461= on NM_018199.3) | Silent (SNP) | VAF 152/380 reads (40%) | called by muse, mutect2, varscan2
- FAM71D | c.582G>A p.T194= | Silent (SNP) | VAF 92/404 reads (23%) | catalogued as COSV61294992; called by muse, mutect2, varscan2
- FAM83F | c.837G>A p.Q279= | Silent (SNP) | VAF 182/381 reads (48%) | called by muse, mutect2, varscan2
- FBXW10 | c.1587G>A p.K529= | Silent (SNP) | VAF 65/265 reads (25%) | called by muse, mutect2, varscan2
- FGA | c.31C>T p.L11= | Silent (SNP) | VAF 142/297 reads (48%) | catalogued as COSV57394977; called by muse, mutect2, varscan2
- FNDC1 | c.1971C>T p.L657= | Silent (SNP) | VAF 237/428 reads (55%) | catalogued as rs1269081856; called by muse, mutect2, varscan2
- FOXD4L3 | c.1206A>G p.P402= | Silent (SNP) | VAF 158/577 reads (27%) | catalogued as rs1554670995; called by muse, varscan2
- FRS3 | c.1215C>T p.R405= | Silent (SNP) | VAF 229/574 reads (40%) | catalogued as COSV52484247; called by muse, mutect2, varscan2
- GCSAML | c.51G>A p.K17= | Silent (SNP) | VAF 49/299 reads (16%) | catalogued as COSV63577594; called by muse, mutect2, varscan2
- GDAP1 | c.30G>A p.G10= | Silent (SNP) | VAF 350/636 reads (55%) | called by muse, varscan2
- GJB5 | c.234C>T p.A78= | Silent (SNP) | VAF 255/511 reads (50%) | called by muse, mutect2, varscan2
- GLI2 | c.297C>T p.S99= | Silent (SNP) | VAF 197/440 reads (45%) | called by muse, mutect2, varscan2
- GOLPH3L | c.120C>T p.D40= | Silent (SNP) | VAF 47/324 reads (15%) | called by muse, mutect2, varscan2
- GPRIN1 | c.1878C>T p.A626= | Silent (SNP) | VAF 33/453 reads (7%) | called by muse, mutect2
- GRIN2B | c.813G>A p.A271= | Silent (SNP) | VAF 174/288 reads (60%) | catalogued as rs201732785, COSV74207906; called by muse, mutect2, varscan2
- GRIN3B | c.1336C>T p.L446= | Silent (SNP) | VAF 213/431 reads (49%) | called by muse, mutect2, varscan2
- GRM4 | c.1902C>T p.F634= | Silent (SNP) | VAF 261/611 reads (43%) | catalogued as COSV65219834; called by muse, mutect2, varscan2
- GRM7 | c.582C>T p.F194= | Silent (SNP) | VAF 71/345 reads (21%) | catalogued as COSV100736791; called by muse, mutect2, varscan2
- GRXCR2 | c.249G>A p.Q83= | Silent (SNP) | VAF 34/384 reads (9%) | called by muse, mutect2
- HAT1 | c.1209G>A p.Q403= | Silent (SNP) | VAF 76/154 reads (49%) | called by muse, mutect2, varscan2
- HFM1 | c.1440G>A p.L480= | Silent (SNP) | VAF 79/178 reads (44%) | called by muse, mutect2, varscan2
- HOXA3 | c.351C>T p.A117= | Silent (SNP) | VAF 435/786 reads (55%) | catalogued as rs779244441; called by muse, mutect2, varscan2
- HYDIN | c.10317C>T p.I3439= | Silent (SNP) | VAF 125/305 reads (41%) | catalogued as COSV66867007; called by muse, mutect2, varscan2
- ICAM2 | c.111G>A p.A37= | Silent (SNP) | VAF 94/721 reads (13%) | catalogued as rs538371118; called by muse, mutect2, varscan2
- IFNA5 | c.561G>A p.R187= | Silent (SNP) | VAF 31/107 reads (29%) | catalogued as rs920400338; called by muse, mutect2
- IGSF3 | c.960C>T p.F320= | Silent (SNP) | VAF 163/368 reads (44%) | catalogued as rs1206625172; called by muse, mutect2, varscan2
- IKBKE | c.789C>T p.L263= | Silent (SNP) | VAF 93/484 reads (19%) | catalogued as COSV65624289; called by muse, mutect2, varscan2
- IL17RB | c.612A>T p.G204= | Silent (SNP) | VAF 166/364 reads (46%) | called by muse, mutect2, varscan2
- ITIH6 | c.3363G>T p.V1121= | Silent (SNP) | VAF 175/297 reads (59%) | catalogued as COSV54490693; called by muse, mutect2, varscan2
- JADE1 | c.2316G>A p.Q772= | Silent (SNP) | VAF 204/441 reads (46%) | called by muse, mutect2, varscan2
- JPH1 | c.1437C>T p.S479= | Silent (SNP) | VAF 549/897 reads (61%) | called by muse, mutect2, varscan2
- KCNH6 | c.1977A>G p.E659= | Silent (SNP) | VAF 69/614 reads (11%) | called by muse, mutect2, varscan2
- KCNN3 | c.1005C>T p.I335= | Silent (SNP) | VAF 218/417 reads (52%) | catalogued as rs754028439, COSV55226805; called by muse, mutect2, varscan2
- KHDC1L | c.216C>T p.V72= | Silent (SNP) | VAF 164/278 reads (59%) | catalogued as rs1376779139, COSV64893514; called by muse, mutect2, varscan2
- KLHL14 | c.1140G>A p.E380= | Silent (SNP) | VAF 86/295 reads (29%) | called by muse, mutect2, varscan2
- KLHL21 | c.1692C>T p.P564= | Silent (SNP) | VAF 109/470 reads (23%) | called by muse, mutect2, varscan2
- KLHL34 | c.655T>C p.L219= | Silent (SNP) | VAF 267/437 reads (61%) | called by muse, mutect2, varscan2
- KMT2B | c.2346C>T p.S782= | Silent (SNP) | VAF 184/429 reads (43%) | catalogued as rs765302675; called by muse, mutect2, varscan2
- LAMC2 | c.1113C>G p.V371= | Silent (SNP) | VAF 68/395 reads (17%) | catalogued as COSV51455432; called by muse, mutect2, varscan2
- LPCAT4 | c.621C>T p.S207= | Silent (SNP) | VAF 86/332 reads (26%) | called by muse, mutect2, varscan2
- MACROH2A1 | c.736C>T p.L246= (on ENST00000510038; = p.L245= on NM_004893.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 152/293 reads (52%) | called by muse, mutect2, varscan2
- MAD1L1 | c.1908C>T p.L636= | Silent (SNP) | VAF 98/729 reads (13%) | catalogued as rs1477630577; called by muse, mutect2, varscan2
- MAGEA10 | c.786C>T p.L262= | Silent (SNP) | VAF 263/424 reads (62%) | called by muse, mutect2, varscan2
- MAGEL2 | c.1308G>A p.L436= | Silent (SNP) | VAF 148/666 reads (22%) | called by muse, mutect2, varscan2
- MDGA1 | c.2418C>T p.I806= | Silent (SNP) | VAF 131/393 reads (33%) | catalogued as rs375230040; called by muse, mutect2, varscan2
- MISP | c.1248G>A p.K416= | Silent (SNP) | VAF 145/587 reads (25%) | called by muse, mutect2, varscan2
- MMP1 | c.1353G>A p.T451= | Silent (SNP) | VAF 52/120 reads (43%) | catalogued as rs1044372464, COSV59510898; called by muse, varscan2
- MRGPRX1 | c.108C>T p.I36= | Silent (SNP) | VAF 75/522 reads (14%) | catalogued as COSV57107605, COSV57107683; called by muse, mutect2, varscan2
- MUC16 | c.4011G>A p.Q1337= | Silent (SNP) | VAF 194/420 reads (46%) | called by muse, mutect2, varscan2
- MUC17 | c.7546C>T p.L2516= | Silent (SNP) | VAF 98/508 reads (19%) | catalogued as COSV60289818; called by muse, mutect2, varscan2
- MYBPC2 | c.2121C>T p.I707= | Silent (SNP) | VAF 160/356 reads (45%) | catalogued as COSV63096500; called by muse, varscan2
- MYH15 | c.192C>T p.I64= | Silent (SNP) | VAF 72/169 reads (43%) | catalogued as rs780355569, COSV56304225; called by muse, mutect2, varscan2
- MYH2 | c.2559G>A p.K853= | Silent (SNP) | VAF 76/359 reads (21%) | catalogued as COSV55432112; called by muse, mutect2, varscan2
- MYH6 | c.5031G>A p.E1677= | Silent (SNP) | VAF 118/501 reads (24%) | called by muse, mutect2, varscan2
- MYO15A | c.7338G>A p.L2446= | Silent (SNP) | VAF 152/358 reads (42%) | catalogued as rs1203829695; called by muse, mutect2, varscan2
- MYO18B | c.6132G>A p.E2044= | Silent (SNP) | VAF 138/426 reads (32%) | called by muse, mutect2, varscan2
- MYO19 | c.1986C>T p.H662= (on ENST00000614623 / NM_001163735.1; = p.H462= on NM_025109.5) | Silent (SNP) | VAF 141/296 reads (48%) | called by muse, mutect2, varscan2
- NCAN | c.2076G>A p.E692= | Silent (SNP) | VAF 93/439 reads (21%) | called by muse, mutect2, varscan2
- NEB | c.7347G>A p.Q2449= | Silent (SNP) | VAF 63/276 reads (23%) | catalogued as rs769042183; called by muse, mutect2, varscan2
- NEURL4 | c.3573G>T p.L1191= | Silent (SNP) | VAF 156/327 reads (48%) | called by muse, mutect2, varscan2
- NID1 | c.1083C>T p.H361= | Silent (SNP) | VAF 83/499 reads (17%) | called by muse, mutect2, varscan2
- NLRP1 | c.2019C>T p.F673= | Silent (SNP) | VAF 80/317 reads (25%) | catalogued as COSV52568266; called by muse, mutect2, varscan2
- NPAS1 | c.477C>T p.F159= | Silent (SNP) | VAF 143/326 reads (44%) | catalogued as rs866230329, COSV71384065, COSV71384074; called by muse, mutect2, varscan2
- NPC1L1 | c.3792C>T p.I1264= | Silent (SNP) | VAF 150/669 reads (22%) | called by muse, mutect2
- NPIPB15 | c.834G>A p.V278= | Silent (SNP) | VAF 244/1942 reads (13%) | catalogued as rs1281599138; called by muse, mutect2
- NRK | c.4672C>T p.L1558= | Silent (SNP) | VAF 53/82 reads (65%) | called by muse, mutect2, varscan2
- NTNG1 | c.1128C>T p.I376= | Silent (SNP) | VAF 112/259 reads (43%) | called by muse, mutect2, varscan2
- NUAK1 | c.45G>A p.L15= | Silent (SNP) | VAF 247/389 reads (63%) | catalogued as rs990672765; called by muse, mutect2, varscan2
- NUP62 | c.804C>T p.S268= | Silent (SNP) | VAF 117/445 reads (26%) | called by muse, mutect2, varscan2
- OIT3 | c.1077A>C p.P359= | Silent (SNP) | VAF 70/343 reads (20%) | called by muse, mutect2, varscan2
- OR10AC1 | c.705C>T p.P235= | Silent (SNP) | VAF 215/614 reads (35%) | called by muse, mutect2, varscan2
- OR10G7 | c.123C>T p.L41= | Silent (SNP) | VAF 114/587 reads (19%) | catalogued as COSV57866717; called by muse, mutect2, varscan2
- OR1M1 | c.318C>T p.F106= | Silent (SNP) | VAF 97/464 reads (21%) | catalogued as COSV70036977; called by muse, mutect2, varscan2
- OR1N2 | c.654C>T p.V218= | Silent (SNP) | VAF 183/433 reads (42%) | catalogued as rs1168267023; called by muse, mutect2, varscan2
- OR4A15 | c.834C>T p.P278= | Silent (SNP) | VAF 113/223 reads (51%) | catalogued as rs765105268; called by muse, mutect2, varscan2
- OR4C6 | c.39G>A p.L13= | Silent (SNP) | VAF 86/187 reads (46%) | called by muse, mutect2, varscan2
- OR56B1 | c.213C>T p.F71= | Silent (SNP) | VAF 143/300 reads (48%) | catalogued as COSV57723134; called by muse, mutect2, varscan2
- OR9H1P | c.45C>T p.F15= | Silent (SNP) | VAF 45/355 reads (13%) | called by muse, mutect2, varscan2
- PANK4 | c.1614C>T p.F538= | Silent (SNP) | VAF 117/482 reads (24%) | called by muse, mutect2, varscan2
- PAPPA2 | c.1227G>A p.G409= | Silent (SNP) | VAF 98/564 reads (17%) | catalogued as COSV62781875; called by muse, mutect2, varscan2
- PATL2 | c.150G>A p.L50= | Silent (SNP) | VAF 177/386 reads (46%) | called by muse, mutect2, varscan2
- PCDH15 | c.4374C>T p.F1458= | Silent (SNP) | VAF 38/123 reads (31%) | catalogued as rs267602528, COSV57267546; called by muse, mutect2, varscan2
- PCDHGB4 | c.1275G>A p.R425= | Silent (SNP) | VAF 30/380 reads (8%) | called by muse, mutect2
- PDHA2 | c.837G>A p.L279= | Silent (SNP) | VAF 166/404 reads (41%) | catalogued as rs1203649158; called by muse, mutect2
- PDIA2 | c.930C>T p.F310= | Silent (SNP) | VAF 63/293 reads (22%) | catalogued as rs746819708; called by muse, mutect2, varscan2
- PHLDB2 | c.2727C>T p.S909= (on ENST00000393925 / NM_001134439.2; = p.S866= on NM_145753.2) | Silent (SNP) | VAF 102/211 reads (48%) | called by muse, mutect2, varscan2
- PIF1 | c.1638C>T p.L546= | Silent (SNP) | VAF 218/490 reads (44%) | called by muse, mutect2, varscan2
- PIK3CG | c.3088C>T p.L1030= | Silent (SNP) | VAF 170/423 reads (40%) | called by muse, mutect2, varscan2
- PLXNA3 | c.2250C>T p.S750= | Silent (SNP) | VAF 205/324 reads (63%) | called by muse, mutect2, varscan2
- POP1 | c.1296C>T p.F432= | Silent (SNP) | VAF 275/453 reads (61%) | called by muse, mutect2, varscan2
- POU4F1 | c.156G>A p.E52= | Silent (SNP) | VAF 170/466 reads (36%) | catalogued as rs1277408529; called by muse, mutect2, varscan2
- POU5F1B | c.511C>T p.L171= | Silent (SNP) | VAF 246/1156 reads (21%) | catalogued as rs1229049549; called by muse, mutect2, varscan2
- PRAMEF6 | c.921G>A p.L307= | Silent (SNP) | VAF 34/256 reads (13%) | called by muse, mutect2, varscan2
- PRKAR2B | c.393C>T p.S131= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs1275371277; called by muse, mutect2, varscan2
- PRKCZ | c.219G>A p.Q73= | Silent (SNP) | VAF 66/392 reads (17%) | called by muse, mutect2
- PRRC2A | c.102G>A p.Q34= | Silent (SNP) | VAF 154/431 reads (36%) | catalogued as rs9688644; called by muse, mutect2, varscan2
- PTPN14 | c.246G>A p.L82= | Silent (SNP) | VAF 90/482 reads (19%) | called by muse, mutect2, varscan2
- PTPRK | c.4158C>T p.F1386= (on ENST00000368215 / NM_001291984.2; = p.F1387= on NM_002844.4) | Silent (SNP) | VAF 128/197 reads (65%) | catalogued as COSV63900725, COSV63907612; called by muse, mutect2, varscan2
- RAB4A | c.190T>C p.L64= | Silent (SNP) | VAF 125/194 reads (64%) | called by muse, mutect2, varscan2
- RABL3 | c.9C>T p.S3= | Silent (SNP) | VAF 104/240 reads (43%) | called by muse, mutect2, varscan2
- RAMAC | c.216G>A p.G72= | Silent (SNP) | VAF 79/226 reads (35%) | catalogued as rs745561686; called by muse, mutect2, varscan2
- RAPGEF2 | c.2634C>T p.T878= | Silent (SNP) | VAF 93/213 reads (44%) | catalogued as rs752511488; called by muse, mutect2, varscan2
- RETSAT | c.1149C>T p.P383= | Silent (SNP) | VAF 65/338 reads (19%) | catalogued as rs543321418, COSV55526724; called by muse, mutect2, varscan2
- RFX1 | c.147C>T p.T49= | Silent (SNP) | VAF 263/505 reads (52%) | catalogued as rs755993440; called by muse, mutect2, varscan2
- RNASE1 | c.408G>A p.V136= | Silent (SNP) | VAF 151/367 reads (41%) | called by muse, mutect2, varscan2
- ROPN1L | c.567C>T p.S189= | Silent (SNP) | VAF 25/226 reads (11%) | catalogued as rs1288293714; called by muse, mutect2, varscan2
- RP1 | c.3117C>T p.L1039= | Silent (SNP) | VAF 127/472 reads (27%) | called by muse, mutect2, varscan2
- RSPH14 | c.1046G>A p.*349= | Silent (SNP) | VAF 139/345 reads (40%) | called by muse, mutect2, varscan2
- RYR1 | c.7161C>T p.S2387= | Silent (SNP) | VAF 100/508 reads (20%) | catalogued as rs766839127, COSV62113457; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN11A | c.108G>A p.E36= | Silent (SNP) | VAF 90/432 reads (21%) | called by muse, mutect2, varscan2
- SCN1A | c.198A>G p.G66= | Silent (SNP) | VAF 74/345 reads (21%) | catalogued as rs779607141; called by muse, mutect2, varscan2
- SCN7A | c.2772G>A p.R924= | Silent (SNP) | VAF 173/409 reads (42%) | catalogued as rs746586197, COSV69268807; called by muse, mutect2, varscan2
- SCRIB | c.4458C>T p.S1486= | Silent (SNP) | VAF 292/1246 reads (23%) | catalogued as rs531139105; called by muse, mutect2, varscan2
- SERPINB2 | c.141G>A p.R47= | Silent (SNP) | VAF 162/454 reads (36%) | catalogued as rs759788422; called by muse, mutect2
- SLC12A4 | c.699C>T p.A233= | Silent (SNP) | VAF 132/291 reads (45%) | called by muse, mutect2, varscan2
- SLC13A3 | c.210C>T p.F70= | Silent (SNP) | VAF 183/490 reads (37%) | called by muse, mutect2, varscan2
- SLC26A7 | c.1308C>T p.I436= | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as rs754205706, COSV52598987, COSV52602864; called by muse, mutect2, varscan2
- SLC34A1 | c.123C>T p.I41= | Silent (SNP) | VAF 176/321 reads (55%) | catalogued as rs759907707; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC5A11 | c.1539G>A p.P513= | Silent (SNP) | VAF 158/349 reads (45%) | catalogued as rs1291939410, COSV61740618; called by muse, mutect2, varscan2
- SLFN14 | c.417C>T p.I139= | Silent (SNP) | VAF 86/374 reads (23%) | called by muse, mutect2, varscan2
- SOX5 | c.213T>A p.S71= | Silent (SNP) | VAF 73/266 reads (27%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.1896G>A p.G632= | Silent (SNP) | VAF 272/988 reads (28%) | catalogued as rs1332519177; called by muse, varscan2
- SPATC1L | c.945C>T p.F315= (on ENST00000291672 / NM_001142854.2; = p.F161= on NM_032261.5) | Silent (SNP) | VAF 133/659 reads (20%) | called by muse, mutect2
- SPHKAP | c.2220G>A p.E740= | Silent (SNP) | VAF 89/392 reads (23%) | called by muse, mutect2, varscan2
- SYNGR1 | c.63C>T p.V21= | Silent (SNP) | VAF 65/311 reads (21%) | called by muse, mutect2, varscan2
- TAS1R1 | c.1620G>A p.G540= | Silent (SNP) | VAF 72/339 reads (21%) | catalogued as rs780109986, COSV59839631; called by muse, mutect2, varscan2
- TDRD15 | c.1695T>C p.F565= | Silent (SNP) | VAF 24/84 reads (29%) | called by muse, mutect2, varscan2
- TF | c.357G>A p.V119= | Silent (SNP) | VAF 57/264 reads (22%) | called by muse, mutect2, varscan2
- TFR2 | c.555C>T p.R185= | Silent (SNP) | VAF 200/559 reads (36%) | catalogued as rs769507636; called by muse, mutect2, varscan2
- THSD7A | c.3951C>T p.P1317= | Silent (SNP) | VAF 279/521 reads (54%) | catalogued as rs370125876; called by muse, mutect2, varscan2
- TMCC2 | c.1693C>T p.L565= | Silent (SNP) | VAF 66/360 reads (18%) | called by muse, mutect2
- TMEM132C | c.3222C>T p.I1074= | Silent (SNP) | VAF 179/313 reads (57%) | catalogued as rs1012778988; called by muse, mutect2, varscan2
- TMEM63B | c.2379G>A p.G793= | Silent (SNP) | VAF 182/514 reads (35%) | catalogued as COSV52482595; called by muse, mutect2, varscan2
- TNFRSF21 | c.1887C>T p.F629= | Silent (SNP) | VAF 187/445 reads (42%) | catalogued as rs777137969; called by muse, mutect2, varscan2
- TNFSF15 | c.642C>T p.L214= | Silent (SNP) | VAF 154/270 reads (57%) | catalogued as rs780282454, COSV65010443; called by muse, varscan2
- TNN | c.2085G>A p.Q695= | Silent (SNP) | VAF 66/455 reads (15%) | catalogued as COSV99512708; called by muse, mutect2, varscan2
- TPRG1 | c.486A>G p.Q162= | Silent (SNP) | VAF 38/177 reads (21%) | called by muse, mutect2, varscan2
- TPX2 | c.63C>T p.S21= | Silent (SNP) | VAF 97/289 reads (34%) | called by muse, mutect2, varscan2
- TRABD2B | c.318G>A p.G106= | Silent (SNP) | VAF 343/575 reads (60%) | called by muse, mutect2, varscan2
- TRDJ3 | c.30C>T p.F10= | Silent (SNP) | VAF 134/273 reads (49%) | catalogued as rs773804495; called by muse, mutect2, varscan2
- TRIM66 | c.612C>T p.F204= | Silent (SNP) | VAF 69/345 reads (20%) | called by muse, mutect2, varscan2
- TRPV4 | c.1119C>T p.P373= | Silent (SNP) | VAF 154/263 reads (59%) | called by muse, mutect2, varscan2
- TRPV6 | c.1524C>T p.F508= | Silent (SNP) | VAF 205/516 reads (40%) | catalogued as rs200231244, COSV63893254, COSV63893634; called by muse, mutect2, varscan2
- TTC24 | c.1464C>T p.F488= | Silent (SNP) | VAF 156/272 reads (57%) | catalogued as rs1232582558; called by muse, mutect2, varscan2
- TTN | c.24768C>T p.I8256= (on ENST00000591111; = p.I7329= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 63/270 reads (23%) | catalogued as rs878991106, COSV59945668; called by muse, mutect2, varscan2
- TTN | c.18792G>A p.G6264= (on ENST00000591111; = p.G5337= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/191 reads (18%) | called by muse, mutect2, varscan2
- TUBGCP5 | c.2703C>T p.I901= | Silent (SNP) | VAF 115/293 reads (39%) | called by muse, mutect2, varscan2
- TXNDC2 | c.951C>T p.S317= (on ENST00000306084 / NM_001098529.2; = p.S250= on NM_032243.6) | Silent (SNP) | VAF 309/664 reads (47%) | called by muse, varscan2
- TXNRD3 | c.999C>T p.C333= | Silent (SNP) | VAF 67/299 reads (22%) | called by muse, mutect2, varscan2
- URB2 | c.3039C>T p.I1013= | Silent (SNP) | VAF 86/455 reads (19%) | called by muse, mutect2, varscan2
- UROC1 | c.1851G>A p.G617= | Silent (SNP) | VAF 86/362 reads (24%) | called by muse, mutect2
- UROC1 | c.912G>A p.R304= | Silent (SNP) | VAF 100/190 reads (53%) | catalogued as rs267599594, COSV52031041; called by muse, mutect2, varscan2
- UROC1 | c.87C>T p.A29= | Silent (SNP) | VAF 112/450 reads (25%) | called by muse, mutect2, varscan2
- WDFY4 | c.2298C>T p.I766= | Silent (SNP) | VAF 82/322 reads (25%) | called by muse, mutect2, varscan2
- ZC3H4 | c.2274C>T p.V758= | Silent (SNP) | VAF 227/532 reads (43%) | called by muse, mutect2, varscan2
- ZNF207 | c.1260C>T p.P420= | Silent (SNP) | VAF 65/283 reads (23%) | catalogued as rs1421984537; called by muse, mutect2, varscan2
- ZNF263 | c.78G>A p.Q26= | Silent (SNP) | VAF 94/431 reads (22%) | called by muse, mutect2, varscan2
- ZNF436 | c.783G>A p.R261= | Silent (SNP) | VAF 183/401 reads (46%) | called by muse, mutect2, varscan2
- ZNF616 | c.915C>T p.S305= | Silent (SNP) | VAF 67/340 reads (20%) | called by muse, mutect2, varscan2
- ZNF729 | c.117G>A p.R39= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as rs764732572; called by muse, mutect2, varscan2
- ACADVL | chr17:7217777 G>A | 5'Flank (SNP) | VAF 147/332 reads (44%) | called by muse, mutect2, varscan2
- AGAP3 | c.224-1724C>T | Intron (SNP) | VAF 75/218 reads (34%) | called by muse, mutect2, varscan2
- APOL1 | c.*529G>A | 3'UTR (SNP) | VAF 176/365 reads (48%) | called by muse, mutect2, varscan2
- ASPH | c.323-11825T>C | Intron (SNP) | VAF 84/331 reads (25%) | called by muse, mutect2, varscan2
- C4orf50 | chr4:5990360 C>T | 5'Flank (SNP) | VAF 57/292 reads (20%) | called by muse, mutect2, varscan2
- C9orf129 | n.717G>A | RNA (SNP) | VAF 71/254 reads (28%) | called by muse, mutect2, varscan2
- CLN5 | c.*152G>A | 3'UTR (SNP) | VAF 142/377 reads (38%) | called by muse, mutect2, varscan2
- DAPK2 | c.858+1578C>T | Intron (SNP) | VAF 67/292 reads (23%) | catalogued as rs1449256048; called by muse, mutect2, varscan2
- DIP2C | c.85+38611C>T | Intron (SNP) | VAF 87/307 reads (28%) | called by muse, mutect2, varscan2
- DLG2 | c.1978+3490C>T | Intron (SNP) | VAF 30/157 reads (19%) | catalogued as rs867282337; called by muse, mutect2, varscan2
- FBXL13 | c.496-5538G>A | Intron (SNP) | VAF 138/408 reads (34%) | called by muse, mutect2, varscan2
- GCNT2 | c.925+27337G>A | Intron (SNP) | VAF 225/583 reads (39%) | catalogued as rs370701306; called by muse, mutect2, varscan2
- IGFL2 | c.19+717C>T | Intron (SNP) | VAF 134/292 reads (46%) | called by muse, varscan2
- KCTD13 | c.414+180C>T | Intron (SNP) | VAF 62/262 reads (24%) | catalogued as rs1000326983; called by muse, mutect2, varscan2
- LEKR1 | c.*1018G>A | 3'UTR (SNP) | VAF 40/178 reads (22%) | catalogued as COSV62965563; called by muse, mutect2, varscan2
- LIMCH1 | c.935+7317C>T | Intron (SNP) | VAF 63/273 reads (23%) | catalogued as rs1378732984; called by muse, mutect2, varscan2
- LINC02881 | n.282G>A | RNA (SNP) | VAF 141/433 reads (33%) | called by muse, mutect2, varscan2
- MUCL3 | c.947-761C>T | Intron (SNP) | VAF 249/807 reads (31%) | called by muse, mutect2, varscan2
- NXF5 | n.834C>T | RNA (SNP) | VAF 126/231 reads (55%) | catalogued as rs1236525560, COSV53789882; called by muse, mutect2, varscan2
- PKD1L2 | chr16:81139545 G>A | 5'Flank (SNP) | VAF 142/307 reads (46%) | called by muse, mutect2, varscan2
- PLEKHG5 | c.25-7773C>A | Intron (SNP) | VAF 119/272 reads (44%) | called by muse, mutect2, varscan2
- PTPRT | c.*6086C>T | 3'UTR (SNP) | VAF 127/350 reads (36%) | called by muse, mutect2, varscan2
- SFTPB | c.-22G>A | 5'UTR (SNP) | VAF 59/326 reads (18%) | called by muse, mutect2, varscan2
- SORBS2 | c.684+7680G>A | Intron (SNP) | VAF 128/528 reads (24%) | called by muse, mutect2, varscan2
- TAFA3 | c.*30G>A | 3'UTR (SNP) | VAF 129/314 reads (41%) | catalogued as rs775384603; called by muse, mutect2, varscan2
- TCEANC2 | c.-42-37T>A | Intron (SNP) | VAF 50/261 reads (19%) | called by muse, mutect2, varscan2
- TMEM272 | chr13:51813320 C>A | 3'Flank (SNP) | VAF 82/204 reads (40%) | called by muse, mutect2, varscan2
- TMEM272 | chr13:51813321 A>C | 3'Flank (SNP) | VAF 81/201 reads (40%) | called by muse, mutect2, varscan2
- Z99774.2 | chr22:26670145 C>T | 5'Flank (SNP) | VAF 77/213 reads (36%) | catalogued as rs1407245781; called by muse, mutect2, varscan2
